Surgical pathology report (de-identified scan), TCGA case TCGA-TN-A7HL, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site  Ohio State University, specimen TCGA-TN-A7HL-01A (Primary Tumor).

[page 1 of 7]
ICD-O-3
Carcinoma, squamous cell NOS
807013
Site Hypopharynx NOS
C13.9
p13 9/26/13

Surgical Pathology Report

--- Clinical History ---

Cancer of hypopharynx . Medical history: Smoking. Alcoholism.
Chronic bronchitis with emphysema. Squamous cell carcinoma of larynx.

---Final Pathologic Diagnosis---

Right superior laryngeal nerve margin, biopsy:
Negative for Invasive Squamous Cell Carcinoma.

Left hypopharynx margin, biopsy:
Negative for Invasive Squamous Cell Carcinoma.

Right hypopharynx margin, biopsy:
Negative for Invasive Squamous Cell Carcinoma.

Inferior hypopharynx margin, biopsy:
Negative for Invasive Squamous Cell Carcinoma.

Right superior pharynx margin, biopsy:
Negative for Invasive Squamous Cell Carcinoma.

Trachea margin, biopsy:
Negative for Invasive Squamous Cell Carcinoma.

Tongue base margin, biopsy:
Negative for Invasive Squamous Cell Carcinoma.

Cricoid lymph node, excision:
One Lymph Node, Negative for Metastatic Squamous Cell Carcinoma

(0/1).

Right neck, Levels II-IV, dissection:
Metastatic Squamous Cell Carcinoma Involving Three of

[page 2 of 7]
Twenty-Nine Lymph Nodes (3/29).

- Level II: 2/6; Level III: 1/10; Level IV: 0/13.
- The Largest Positive Lymph Node Measures 3.3cm in Greatest Dimension (Level II).
- Extracapsular Nodal Extension is Present.

- Left neck, Levels II-IV, dissection:
Thirty-five Lymph Nodes, Negative for Metastatic Squamous Cell Carcinoma (0/35).
- Level II: 0/15; Level III: 0/7; Level IV: 0/13.

Additional left level IV lymph nodes, dissection:
Five Lymph Nodes, Negative for Metastatic Squamous Cell Carcinoma (0/5).

- Larynx, pharynx, right thyroid lobe, resection:
Invasive Moderately Differentiated HPV-Associated Squamous Cell Carcinoma, Located in the Right Hypopharynx with Involvements of the Right Piriform Sinus and Right Vocal Cord. (See Synoptic Report)
- Tumor Measures 4.7 x 3.7 x 2.6cm in Size.
- Tumor Abuts the Thyroid Cartilage But Does Not Violate It.
- Thyroid Gland, Negative for Invasive Squamous Cell Carcinoma.
- Tumor is at 0.09mm and .15mm from the Right Lateral Hypopharyngeal and Base of Tongue Soft Tissue Edges/Margins Respectively (See Note)

Note: Additional specimens designated as "Right Hypopharynx Margin" (part C) and "Tongue Base Margin" (part G) Are Negative for Malignancy.

Additional right Level II lymph node, excision:
One Lymph Node, Negative for Metastatic Squamous Cell Carcinoma (0/1).

SYNOPTIC REPORT FOR CANCER OF THE PHARYNX:

Specimen type: Total Laryngectomy, Partial Pharyngectomy, Right Thyroid Lobectomy and Bilateral Neck Dissections (Levels II-IV)
Tumor site: Right Hypopharynx with Involvement of the Right Piriform and Ipsilateral Vocal Cords
Tumor focality (single focus/multifocal): Single Focus
Tumor size: 4.7 x 3.7 x 2.6cm
Tumor gross configuration: Exophytic and Ulcerative
Histologic type: HPV-Associated Squamous Cell Carcinoma
Tumor grade: Moderately Differentiated
Lymphatic/vascular invasion: Yes
Perineural invasion: Yes
Tumor extent:
Intramucosal lesion: Yes
Adjacent soft tissues and/or bone (primary tumor related):
Margins:
Mucosal margins: Negative
Soft tissue margins: Negative
Distance of tumor to nearest margin: Tumor is at 0.09mm and .15mm from the Closest Right Lateral Hypopharyngeal and Tongue Base Edges/Margins respectively. However, Additional Specimen Designated as "Right Hypopharynx Margin" (part C) and "Tongue Base Margin" (part G) Are Negative for Malignancy
Lymph nodes:
Total number examined: 71
Number positive: 3

[page 3 of 7]
Extranodal extension: Yes
Size of largest positive lymph node: 3.3cm
Neoadjuvant therapy: No
Ancillary Studies: Please refer to _____ for Results of p16/HPV-16
Status
pTNM: pT3 pN2b

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists Protocols and the AJCC Cancer Staging Manual, 7th edition, 2010, for the reporting of cancer specimens.

Primary Tumor (pT): Hypopharynx

___ pT1: Tumor limited to one subsite of hypopharynx and/or 2 cm or less in greatest dimension
___ pT2: Tumor invades more than one subsite of hypopharynx or an adjacent site, or measures more than 2 cm but not more than 4 cm in greatest dimension without fixation of hemilarynx
X pT3: Tumor measures more than 4 cm in greatest dimension or with fixation of hemilarynx or extension to esophagus
___ pT4a: Moderately advanced local disease. Tumor invades thyroid/cricoid cartilage, hyoid bone, thyroid gland, or central compartment soft tissue#
___ pT4b: Very advanced local disease. Tumor invades prevertebral fascia, encases carotid artery, or involves mediastinal structures
#Note: Central compartment soft tissue includes prelaryngeal strap muscles and subcutaneous fat.

Regional Lymph Nodes (pN)

___ pNX: Cannot be assessed
___ pN0: No regional lymph node metastasis

Regional Lymph Nodes (pN): Oropharynx and Hypopharynx#

___ pN1: Metastasis in a single ipsilateral lymph node, 3 cm or less in greatest dimension
___ pN2: Metastasis in a single ipsilateral lymph node, more than 3 cm but not more than 6 cm in greatest dimension, or in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension, or in bilateral or contralateral lymph nodes, none more than 6 cm in greatest dimension
___ pN2a: Metastasis in a single ipsilateral lymph node, more than 3 cm but not more than 6 cm in greatest dimension
X pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6cm in greatest dimension
___ pN2c: Metastasis in bilateral or contralateral lymph nodes, none more than 6 cm in greatest dimension
___ pN3: Metastasis in a lymph node more than 6 cm in greatest dimension

Specify: Number examined: 71
Number involved: 3

*Size (greatest dimension) of the largest positive lymph node: 3.3cm
# Note: Metastases at level VII are considered regional lymph node metastases. Midline nodes are considered ipsilateral nodes.

Distant Metastasis (pM)

X Not applicable
___ pM1: Distant metastasis
*Specify site(s), if known: _____
* Source of pathologic metastatic specimen (specify): _____

[page 4 of 7]
---INTRAOPERATIVE CONSULTATION DIAGNOSIS:---

AF1. Right superior laryngeal nerve margin (Frozen section performed):
- Benign nerve.

Note: Reported to on at

BF1. Left hypopharynx margin (Frozen section performed):
- Benign.

CF1. Right hypopharynx margin (Frozen section performed):
- Benign.

DF1. Inferior hypopharynx margin (Frozen section performed):
- Benign.

EF1. Right superior pharynx margin (Frozen section performed):
- Benign.

FF1. Trachea margin (Frozen section performed):
- Benign.

GF1. Tongue base margin (Frozen section performed):
- Benign.

Note: BF through GF were reported to on at

Examining pathologist

---SPECIMEN(S) RECEIVED:---

A: Surgical margin
B: Surgical margin
C: Surgical margin
D: Surgical margin
E: Surgical margin
F: Surgical margin
G: Surgical margin
H: Lymph node, excision
I: Lymph node, dissection

[page 5 of 7]
J: Lymph node, dissection
K: Lymph node, dissection
L: Larynx, partial/total without lymph nodes
M: Lymph node, excision

---GROSS DESCRIPTION:---

The specimens are received in thirteen properly labeled containers with the patient's name and accession number, seven were submitted for frozen section.

A. The specimen is designated "right superior laryngeal nerve margin" and consists of a 0.2 x 0.2 x 0.1 cm soft tissue fragment. This specimen was submitted entirely for frozen section. All tissue was exhausted at the time of frozen section.

B. The specimen is designated "left hypopharynx margin" and consists of a 0.6 x 0.2 x 0.2 cm soft tissue fragment. This specimen was submitted entirely for frozen section. Frozen section cassette BF1 is resubmitted as received.

C. The specimen is designated "right hypopharynx margin" and consists of a 0.9 x 0.3 x 0.2 cm soft tissue fragment. This specimen was submitted entirely for frozen section. All tissue was exhausted at the time of frozen section.

D. The specimen is designated "inferior hypopharynx margin" and consists of a 0.5 x 0.3 x 0.2 cm soft tissue fragment. This specimen was submitted entirely for frozen section. Frozen section cassette DF1 is resubmitted as received.

E. The specimen is designated "right superior pharynx margin" and consists of a 0.5 x 0.4 x 0.3 cm soft tissue fragment. This specimen was submitted entirely for frozen section. Frozen section cassette EF1 is resubmitted as received.

F. The specimen is designated "trachea margin" and consists of a 0.5 x 0.3 x 0.1 cm soft tissue fragment. This specimen was submitted entirely for frozen section. All tissue was exhausted at the time of frozen section.

G. The specimen is designated "tongue base margin" and consists of a 0.8 x 0.4 x 0.3 cm soft tissue fragment. This specimen was submitted entirely for frozen section. All tissue was exhausted at the time of frozen section.

H. The specimen is designated "cricoid lymph node" and consists of a 0.3 x 0.2 x 0.2 cm lymph node.

I. The specimen is designated "right neck dissection lymph nodes levels 2-4 (stitches: 2 = level 2, 1 = level 4)" and consists of an 11.5 x 4.7 x 2.4 cm portion of fibrofatty tissue without skeletal muscle or segment of internal jugular vein. Two sutures are placed at Level II and one suture at Level IV. Levels II-IV are represented. Six lymph nodes are identified within Level II (one positive), 11 lymph nodes within Level III (one positive), and 14 lymph nodes within Level IV. The lymph nodes range from 0.2 cm in maximum dimension up to 3.3 x 2.8 x 1.4 cm. The largest lymph node is in Level II, and contains a 2.1 cm metastatic deposit.

[page 6 of 7]
Summary of Cassettes: I1, five Level II lymph nodes; I2-3, each cassette contains one section from largest (positive) Level II lymph node; I4, six Level III lymph nodes; I5, three Level III lymph nodes; I6, one bisected Level III lymph node; I7, section from positive Level III lymph node; I8-9, each cassette contains six Level IV lymph nodes; I10, two Level IV lymph nodes

J. The specimen is designated "left neck dissection lymph nodes levels 2-4 (stitches: 2 = level 2, 1 = level 4)" and consists of an 11.0 x 5.0 x 2.0 cm portion of fibrofatty tissue without skeletal muscle or segment of internal jugular vein. Two sutures are placed at Level II and one suture at Level IV. Levels II-IV are represented. Twelve lymph nodes are identified within Level II, seven lymph nodes within Level III, and 12 lymph nodes within Level IV. The lymph nodes range from 0.3 cm in maximum dimension up to 1.7 x 0.6 x 0.3 cm. The largest lymph node is in Level II.

Summary of Cassettes: J1, six Level II lymph nodes; J2-3, each cassette contains three Level II lymph nodes; J4, four Level III lymph nodes; J5, three Level III lymph nodes; J6, six Level IV lymph nodes; J7, four Level IV lymph nodes; J8, two Level IV lymph nodes

K. The specimen is designated "additional left level 4 lymph nodes" and consists of a 3.0 x 1.5 x 1.0 cm portion of fibrofatty tissue. Five possible lymph nodes are identified, ranging from 0.2 cm in maximum dimension up to 1.7 x 1.4 x 0.6 cm.

Summary of Cassettes: K1, four lymph nodes; K2, one bisected lymph node

L. The specimen is designated "total larynx, partial pharynx, right thyroid lobe" and consists of an intact total laryngectomy with attached hyoid bone (8.4 x 6.7 x 6.4 cm), attached right thyroid lobe (5.2 x 3.1 x 2.7 cm), and portion of right hypopharynx. The soft tissue and mucosal margins are inked black. The right hypopharynx is extensively involved by a 4.7 x 3.7 x 2.6 cm gray-tan, feathery, irregularly margined submucosal mass that manifests as a 2.8 x 1.1 cm ulcerated mucosal lesion within the right piriform sinus, involving the lateral border of the aryepiglottic fold, and is 0.7 cm from both the superior and inferior hypopharyngeal mucosal margins and 0.6 cm from the right lateral hypopharyngeal mucosal margin. The mass itself diffusely infiltrates the soft tissues, abuts the base of tongue (superior) soft tissue margin, and is 0.1 and 0.2 cm from the right anterior and right lateral soft tissue margins, respectively. The mass is 3.2 cm from the tracheal margin. The mass does not involve the laryngeal vestibule, glottic or subglottic regions. There is no apparent involvement of the cricoid cartilage, tracheal lumen, or hyoid bone. The mass appears confined to the right side and does not cross the midline. The mass surrounds (and possibly involves) the thyroid cartilage. The thyroid parenchyma is red-brown and smooth, without nodularity or definable mass lesion.

Summary of Cassettes: L1, mass with mucosal lesion, perpendicular to right superior hypopharyngeal mucosal margin; L2, right aryepiglottic fold with mucosal lesion and mass; L3, mucosal lesion and mass perpendicular to right lateral hypopharyngeal mucosal margin; L4, mucosal lesion and mass perpendicular to inferior hypopharyngeal mucosal margin; L5, right true and false vocal cords; L6, mass perpendicular to base of tongue soft tissue margin; L7, mass perpendicular to right lateral hypopharyngeal soft tissue margin; L8-9, mass perpendicular to right anterior soft tissue margin (to include thyroid cartilage); L10, mass in relation to laryngeal mucosa; L11,

[page 7 of 7]
epiglottis; L12, tracheal margin, shave; L13, left true and false vocal cords; L14, left piriform sinus and aryepiglottic fold, perpendicular to left lateral hypopharyngeal mucosal margin; L15, left anterior soft tissue margin, perpendicular; L16-17, right thyroid, representative sections; L18, isthmus margin, shave

M. The specimen is designated "additional right level 2 lymph nodes" and consists of a 2.0 x 1.5 x 1.0 cm aggregate of fibrofatty tissue. One possible lymph node is identified, measuring 0.7 x 0.5 x 0.3 cm.

Summary of Cassettes: M1, one lymph node

HPV A Discrepancy		☒
Local/Regional Primary Noted		☒

Source: NCI Genomic Data Commons file a36bff6c-4c2d-41f4-9d15-be9cffeab134 (TCGA-TN-A7HL.BED776A5-936A-468C-B469-EF9FB12109D1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).